Surgical pathology report (de-identified scan), TCGA case TCGA-06-5417, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5417-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Report

CGA-06-5417

CLINICAL HISTORY

_____ experienced severe left _____ and some _____

_____ On imaging there are two contiguous lesions. One is large, parasagittal in the superior left frontal, has irregular enhancement, is probably extra axial, and is fed by a branch of the middle meningeal artery; this lesion is embolized. The second lesion is partially cystic, 5.5 cm across, and is located inferiorly in the anterior frontal lobe; the mass enhances slightly and exerts mass effect in the lateral ventricle.

OPERATIVE DIAGNOSES

Brain tumors

Operation/Specimen: A: Brain, excision biopsy
B: Brain, 1, excision biopsy
C: Brain, intra-axial, excision biopsy
D: Brain, medial portion, excision biopsy
E: Brain, medial portion, excision biopsy

PATHOLOGICAL DIAGNOSIS:

- A and B.
1. Brain, sites not specified, excision: Meningioma (WHO I), extensively necrotic, previously embolized.
2. MIB-1 proliferation index: 2%.
C, D, and E. Brain, intraaxial, medial portion (FS), and medial

[page 2 of 6]
portion-permanent, excision:

1. Glioblastoma.
2. MIB-1 proliferation index: 30% to 35%.
- See Microscopy Description and Comment.

COMMENT

Parts A and B are portions of a fibrous meningioma that is extensively necrotic. In the few better preserved areas the mitotic index is about one / ten high power fields, and the proliferation index is about 2% in the more active areas. There is not brain tissue in the specimens submitted.

Parts C, D, and E contain portions of a glial neoplasm that heavily infiltrates cerebral cortex and adjacent white matter. The neoplastic cells are very pleomorphic with frequent giant nuclei or multinucleated cells. The tumor has prominent nuclear anaplasia, frequent mitotic activity, prominent microvascular cellular proliferation, and zones of necrosis, some with pseudopalisading. The MIB-1 proliferation index is high, up to 35%. The findings are interpreted as those of a glioblastoma (WHO grade IV).

In part C the tumor is more infiltrative. In parts D and E the tumor is more solid and less differentiated.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]
Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

[page 3 of 6]
Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

POSITIVE: Allelic loss on chromosome arm 19q is detected.

Allelic loss on chromosome arm 1p is not detected.

Informative loci are: D1S548, D1S1592, D1S552, D19S219, and PLA2G4C

Results-Comments

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

[page 4 of 6]
stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, excision biopsy: Necrotic tumor, probably epithelioid (C/W meningioma, [REDACTED] other). [REDACTED] Touch preparation smears performed at [REDACTED] and [REDACTED] results reported to the Physician of Record.

C.

Brain, intra-axial, excision biopsy: Primary brain tumor, glial, high histological grade (R/O oligo component, other). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Meningioma", received fresh, portion of capsule, 2.0 cm across, containing soft, creamy, greyish-white necrotic material. In total, A1 and A2.

B.

"Meningioma, permanent," received fresh multiple fragments, 2.5 x 1.8 x 0.7 cm. Diffluent, creamy-white, necrotic. In total, B1-B3.

C.

"Intraaxial tumor," received fresh, four fragments, 1.0 cm in aggregate. Semi firm, greyish-pink, glistening. In total, C1 and C2.

D.

"Medial portion (FS)," received fresh, two fragments, 2.5 cm across in aggregate. Firm, greyish-white, smooth cut surfaces. In total, D1-D3.

[page 5 of 6]
E.

"Medial portion, permanent", received fresh, three fragments, 2.7 cm across in aggregate. Firm, tannish-white, smooth cut surfaces. In total, E1-E3.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY:

The meningeal tumor has positive reaction with EMA. With the MIB-1, the proliferation index is about 2%; around zones of necrosis, it may be somewhat

higher, as may be expected in tumors with embolization-induced necrosis.

In the intra axial tumor, the GFAP demonstrates a dense gliofibrillary background throughout the specimen, even in the more cellular, less differentiated zones of the neoplasm. The synaptophysin and neurofilament

depict the tumor densely infiltrating cerebral cortex and adjacent white

matter, and absence of a neuronal neoplastic component. The great majority of

neoplastic cells strongly over express the p53 protein. With the MIB-1 the

proliferation index ranges between 30% and 35% in the more densely infiltrated areas.

ICD-9(s):

225.2 225.2 191.9

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part B: Brain, 1, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
EMA-DA x 1	1		
H/E x 1	1		
MIB1-DA x 1	1		
H/E x 1	2		

[page 6 of 6]
H/E x 1

3

Part C: Brain, intra-axial, excision biopsy

Taken:

Received:

Stain/cnt

Block

Ordered

Comment

H/E x 1

1

TPS H/E x 1

1

H/E x 1

2

Part D: Brain, medial portion, excision biopsy

Taken:

Received:

Stain/cnt

Block

Ordered

Comment

x 1

1

microdissection.

CD34-DA x 1

1

mGFAP-DA x 1

1

H/E x 1

1

MGMT-curls x 1

1

MIB1-DA x 1

1

NeuN x 1

1

NF2F11 x 1

1

P53DO7 x 1

1

Synap-DA x 1

1

TPS H/E x 1

1

H/E x 1

2

H/E x 1

3

Part E: Brain, medial portion, excision biopsy

Taken:

Received:

Stain/cnt

Block

Ordered

Comment

H/E x 1

1

H/E x 1

2

mGFAP-DA x 1

3

H/E x 1

3

MIB1-DA x 1

3

NF2F11 x 1

3

*** End of Report ***

Source: NCI Genomic Data Commons file b39aabce-5b91-402e-ad42-b706cc14d7e5 (TCGA-06-5417.6984F96F-E27E-4143-B7DB-54E97DBAA25C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).